Surgical pathology report (de-identified scan), TCGA case TCGA-02-2470, project TCGA-GBM (Glioblastoma Multiforme), tissue source site MD Anderson Cancer Center, specimen TCGA-02-2470-01A (Primary Tumor).

TCGA-02-2470

DIAGNOSIS

- (A) BRAIN, PORTION OF ENHANCING NODULE, CRANIOTOMY:
RECURRENT/RESIDUAL GLIOBLASTOMA (WHO GRADE IV) (SEE COMMENT).
- (B) BRAIN, RIGHT TEMPORAL LOBECTOMY, CRANIOTOMY:
RECURRENT/RESIDUAL GLIOBLASTOMA (WHO GRADE IV) (SEE COMMENT).

COMMENT

Tissue sections show a diffuse high grade astrocytoma with nuclear pleomorphism, increased mitoses, vascular proliferation, fibrin thrombi and necrosis, which is more prominent on specimen B. In addition, focal perivascular lymphocytic infiltration and macrophage infiltration is seen. Vessels with hyalinized walls are also present.

GROSS DESCRIPTION

(A) PORTION OF ENHANCING NODULE, FROZEN AND PERMANENT - It consists of a rounded fragment of gray-tan soft tissue measuring 2.5 x 2.0 x 0.8 cm. The external surface is irregular and focally hemorrhagic. On cross sections the tissue shows a gray-tan smooth cut surface. Grossly no areas of necrosis are identified. Smear preparations are performed. A portion of the tissue is frozen for intraoperative consultation in cassette A1. The remaining tissue is submitted for microscopic examination in three cassettes labeled A2-A4.

SECTION CODE: A1, frozen section; A2-A4, permanent section.

X: A1, RECURRENT/RESIDUAL MALIGNANT GLIOMA.

(B) RIGHT TEMPORAL LOBECTOMY PERMANENT - It consists of an irregular portion of brain tissue measuring 5.0 x 4.0 x 0.6 cm. The resection margin is irregular and hemorrhagic. The opposite surface shows mildly congested leptomeninges. On cross sections a poorly circumscribed tumor is identified in the white matter. The tumor shows a variegated appearance with cyst and areas of necrosis and hemorrhage. A portion of the specimen is submitted for Tissue Bank. The remaining specimen is submitted for microscopic examination in seven cassettes labeled B1-B7.

CLINICAL HISTORY

None given.

SNOMED CODES

T-A2000, M-94403

Source: NCI Genomic Data Commons file fbb35305-c492-49f5-8c5b-6a7eb0c72c85 (TCGA-02-2470.E21F66D9-E124-43D7-81FE-489D15D69CBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).